Somatic mutation profile of tumor specimen HCM-BROD-0745-C43-06B (aliquot HCM-BROD-0745-C43-06B-21D-A85C-36) from HCMI case HCM-BROD-0745-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,306 days).
Specimen HCM-BROD-0745-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eb5ce03-32ad-44c5-b57e-7450ccba53e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0745-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0745-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21d87f4a-8148-45f6-85d5-ea98be79228c

The open-access MAF lists 512 somatic variants for this specimen: 321 protein-altering or splice-affecting, 174 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 174, Nonsense Mutation 20, Intron 11, Splice Region 6, Frame Shift Ins 4, 3'Flank 3, 3'UTR 2, Frame Shift Del 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LPA | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 75/352 reads (21%) | catalogued as rs121912503, COSV60296281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs779263287; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 193/715 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs867693203; called by muse, mutect2, varscan2
- AFF2 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 160/281 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53977388; called by muse, mutect2, varscan2
- AGO3 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99867878; called by muse, mutect2, varscan2
- AHNAK | c.13915C>T p.P4639S | Missense Mutation (SNP) | VAF 67/460 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57211015; called by muse, varscan2
- ALK | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 176/589 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV66557187; called by muse, mutect2, varscan2
- AMER3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 152/586 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV58465537; called by muse, varscan2
- ARHGAP32 | c.5686C>T p.P1896S (on ENST00000310343 / NM_001378025.1; = p.P1547S on NM_014715.4) | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as rs1170742059; called by muse, mutect2, varscan2
- ASXL3 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 94/408 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99325841; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 180/341 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, varscan2
- ATP13A1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs763096515, COSV52284614; called by muse, mutect2, varscan2
- BMP4 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 138/510 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55415221, COSV55415481, COSV99816684; called by muse, varscan2
- CACNA1H | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 150/797 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as rs768197900; ClinVar: likely benign; called by muse, varscan2
- CADPS | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV51872873; called by muse, mutect2, varscan2
- CAMSAP2 | c.1579C>T p.H527Y (on ENST00000236925 / NM_001297707.2; = p.H516Y on NM_203459.3) | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV99373049; called by muse, mutect2, varscan2
- CAPZA3 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 146/584 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99856427; called by muse, varscan2
- CCDC40 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 97/529 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs760397607; called by muse, mutect2, varscan2
- CD163 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 200/656 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63133423; called by muse, mutect2, varscan2
- CD163 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 164/661 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV63136965; called by muse, mutect2, varscan2
- CD2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs769894316; called by muse, varscan2
- CD247 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 141/512 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100758350; called by muse, mutect2, varscan2
- CDH12 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 121/395 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs374444907; called by muse, mutect2, varscan2
- CDHR1 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756969177; called by muse, varscan2
- CELSR2 | c.6919C>T p.R2307C | Missense Mutation (SNP) | VAF 162/612 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs1366132430, COSV54768919; called by muse, varscan2
- CHRNB3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 129/325 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1418024205, COSV51493359, COSV51495659; called by muse, mutect2, varscan2
- CKMT1A | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 68/600 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767898760; called by muse, varscan2
- CLEC18B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 110/588 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1473630019; called by muse, mutect2, varscan2
- CLVS2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.328); catalogued as COSV51565713; called by muse, mutect2, varscan2
- CNTN5 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867933506, COSV54343942; called by muse, mutect2, varscan2
- COL12A1 | c.9091A>T p.N3031Y | Missense Mutation (SNP) | VAF 104/604 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100485445; called by muse, varscan2
- COL12A1 | c.7840C>T p.P2614S | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs772870762, COSV59397992; called by muse, mutect2, varscan2
- CRTC2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100135636; called by muse, varscan2
- CRYBG1 | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs767966320, COSV64810992; called by muse, mutect2, varscan2
- CYLC1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 127/257 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV61413401; called by muse, mutect2, varscan2
- DEFB119 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 174/550 reads (32%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as rs1184134834; called by muse, mutect2, varscan2
- DMBT1 | c.5383G>A p.D1795N (on ENST00000338354 / NM_001377530.1; = p.D1038N on NM_004406.3) | Missense Mutation (SNP) | VAF 263/546 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760683143, COSV57535850, COSV57547017; called by muse, varscan2
- DNAH5 | c.6764G>A p.R2255Q | Missense Mutation (SNP) | VAF 224/757 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1317585354, COSV54235046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.11186C>T p.P3729L | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs142032754; called by muse, varscan2
- DNAH9 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52359825; called by muse, mutect2, varscan2
- DYNC2H1 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1409098412; called by muse, mutect2, varscan2
- EGFR | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 149/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1343888047; called by muse, mutect2, varscan2
- EML6 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 92/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62868220; called by muse, varscan2
- EPPK1 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 74/520 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1470942284; called by muse, mutect2, varscan2
- EVPL | c.4711G>A p.G1571R | Missense Mutation (SNP) | VAF 116/729 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774963318; called by muse, varscan2
- FAM53C | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 215/555 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1252345775; called by muse, mutect2, varscan2
- FBXL13 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100502235; called by muse, varscan2
- FDXACB1 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs1381030608; called by muse, mutect2, varscan2
- FECH | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 92/383 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs929058991, COSV50491038; called by muse, mutect2, varscan2
- FLG | c.3827G>A p.S1276N | Missense Mutation (SNP) | VAF 121/406 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV64244884; called by muse, mutect2, varscan2
- FLNB | c.7642G>A p.G2548R | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1411322123, COSV99914177; called by muse, mutect2, varscan2
- FLT1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV56728367, COSV56741828; called by muse, varscan2
- FN1 | c.6979G>A p.G2327S (on ENST00000359671 / NM_001365524.2; = p.G2296S on NM_002026.4) | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200155993; called by muse, mutect2, varscan2
- FOLR2 | c.-22C>T | Splice Region (SNP) | VAF 86/471 reads (18%) | catalogued as COSV99995443; called by muse, varscan2
- FOXA3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 229/810 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100141301; called by muse, mutect2, varscan2
- FURIN | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 166/516 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV99184674; called by muse, varscan2
- GAB4 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 210/556 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs776467243; called by muse, varscan2
- GABRE | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 257/428 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.411); catalogued as COSV100944197; called by muse, mutect2, varscan2
- GIPC3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 196/545 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1294965399; called by muse, mutect2, varscan2
- GJB3 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 168/547 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64904835; called by muse, varscan2
- GLB1L3 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV66280825; called by muse, varscan2
- GPATCH2L | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as rs754927074; called by muse, mutect2, varscan2
- GRIA1 | c.222C>T p.F74= | Splice Region (SNP) | VAF 61/152 reads (40%) | catalogued as COSV53596194; called by muse, mutect2, varscan2
- GSE1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 173/421 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as rs150332530; called by muse, mutect2, varscan2
- HTR3A | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55470567; called by muse, varscan2
- HTR5A | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 204/747 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs751769358, COSV55283961, COSV99840023; called by muse, varscan2
- HUNK | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179104958; called by muse, mutect2, varscan2
- ICE1 | c.6067C>T p.P2023S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99663811; called by muse, mutect2, varscan2
- IDH2 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.947); catalogued as COSV51565752; called by muse, mutect2, varscan2
- IGF1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 118/461 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1565970471, CM096029, COSV61033693; called by muse, mutect2, varscan2
- IGFN1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs368275026; called by muse, mutect2, varscan2
- IGHE | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 184/736 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1318124445; called by muse, varscan2
- IGHMBP2 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54825170; called by muse, varscan2
- IMPDH1 | c.790C>T p.Q264* (on ENST00000470772 / NM_001142573.2; = p.Q350* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 126/395 reads (32%) | catalogued as rs1218568607, COSV100118825; called by muse, mutect2, varscan2
- IPO7 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs1323483608, COSV65686656; called by muse, mutect2, varscan2
- IRF2BP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 182/633 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56193324; called by muse, mutect2, varscan2
- KCNJ3 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1239359925, COSV54534586, COSV54540423; called by muse, varscan2
- KERA | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 146/487 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.187); catalogued as rs760337736; called by muse, mutect2, varscan2
- KIAA2012 | c.1543dup p.S515Kfs*3 | Frame Shift Ins (INS) | VAF 124/490 reads (25%) | catalogued as rs1056854543; called by mutect2, varscan2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 148/291 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- KMT2C | c.9181C>T p.Q3061* | Nonsense Mutation (SNP) | VAF 102/579 reads (18%) | catalogued as COSV51516492, COSV51520902; called by muse, varscan2
- KMT2D | c.9941C>T p.S3314F | Missense Mutation (SNP) | VAF 172/686 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1258642596, COSV56407832; called by muse, mutect2, varscan2
- KSR2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 222/848 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100350448; called by muse, mutect2, varscan2
- LAMC3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1011715171; called by muse, varscan2
- LRP10 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 165/607 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62078056; called by muse, mutect2, varscan2
- LRP1B | c.4934C>T p.S1645L | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs375614524; called by muse, mutect2, varscan2
- MAGEB16 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 185/320 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs370569797, COSV67874447; called by muse, varscan2
- MAPT | c.2276G>A p.G759E (on ENST00000262410 / NM_001377265.1; = p.G367E on NM_005910.5) | Missense Mutation (SNP) | VAF 70/355 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52244905; called by muse, mutect2, varscan2
- MCM6 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 123/506 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1291101798; called by muse, mutect2, varscan2
- MEA1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 146/478 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.341); catalogued as rs1435435878; called by muse, mutect2, varscan2
- MGAM2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 202/612 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1469143931; called by muse, varscan2
- MMP16 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54188081, COSV99688787; called by muse, mutect2, varscan2
- MROH1 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 141/416 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs920515598; called by muse, mutect2, varscan2
- MYH10 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 211/469 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs377262737, COSV52614320; called by muse, mutect2, varscan2
- MYH13 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 139/321 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs371327620; called by muse, mutect2, varscan2
- MYO1A | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 167/572 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs774478942; called by muse, mutect2, varscan2
- MYO5A | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as rs770697352, COSV62560722; called by muse, mutect2, varscan2
- N4BP3 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 253/573 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV51062210; called by muse, varscan2
- NEB | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51432175; called by muse, mutect2, varscan2
- NEFL | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99648015; called by muse, varscan2
- NHSL2 | c.1454C>T p.A485V (on ENST00000510661; = p.A851V on NM_001013627.2) | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as rs868409862; called by muse, varscan2
- NIPAL1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55006003; called by muse, mutect2, varscan2
- NISCH | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 215/611 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs139206974; called by muse, mutect2, varscan2
- NOS2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 148/539 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1378739633, COSV104402636; called by muse, mutect2, varscan2
- NPAS2 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 162/595 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs754493741; called by muse, varscan2
- NR1D1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 165/507 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV52844176; called by muse, mutect2, varscan2
- OR2G6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100598070; called by muse, mutect2, varscan2
- OR4A16 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs267602960, COSV59042565, COSV59042689; called by muse, mutect2, varscan2
- OR4C15 | c.790T>G p.F264V (on ENST00000314644; = p.F210V on NM_001001920.2) | Missense Mutation (SNP) | VAF 70/347 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV58952521; called by muse, varscan2
- OR8B2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100899383, COSV66664152; called by muse, mutect2, varscan2
- OTOG | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs914926596, COSV68041396; called by muse, varscan2
- OTOG | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1034866081; called by muse, varscan2
- OTOGL | c.4772C>T p.P1591L (on ENST00000547103; = p.P1582L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54015002; called by muse, mutect2, varscan2
- OXR1 | c.997G>A p.E333K (on ENST00000442977 / NM_001198532.1; = p.E332K on NM_018002.3) | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.352); catalogued as COSV56323771; called by muse, varscan2
- PADI6 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 96/378 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1415465623; called by muse, mutect2, varscan2
- PDGFRB | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 184/533 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV53839666; called by muse, mutect2, varscan2
- PDGFRB | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs754451292, COSV55801133; called by muse, varscan2
- PGLYRP4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 136/590 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750203517; called by muse, mutect2
- PKHD1L1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs757015646, COSV65743461; called by muse, mutect2, varscan2
- PTPRK | c.1912C>G p.H638D | Missense Mutation (SNP) | VAF 143/619 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63905275; called by muse, mutect2, varscan2
- PYHIN1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 66/326 reads (20%) | catalogued as rs144716673; called by muse, varscan2
- RAG2 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV57557131; called by muse, mutect2, varscan2
- REG3G | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 87/463 reads (19%) | catalogued as rs1254267404; called by muse, mutect2, varscan2
- RET | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 292/773 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs539995816, COSV60704171; ClinVar: uncertain significance; called by muse, varscan2
- RIPK3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 120/495 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.772); catalogued as COSV99353514; called by muse, mutect2, varscan2
- RNF114 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 196/670 reads (29%) | catalogued as rs773173342, COSV54869485, COSV99724797; called by muse, mutect2, varscan2
- SDHB | c.423C>T p.P141= | Splice Region (SNP) | VAF 97/320 reads (30%) | catalogued as rs150542357; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SHANK2 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 94/432 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs782565293, COSV99574559, COSV99575388; called by muse, varscan2
- SHANK2 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as rs781983283, COSV53591658; called by muse, mutect2, varscan2
- SI | c.4801C>T p.H1601Y | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52265690, COSV52283499; called by muse, mutect2, varscan2
- SIGLEC9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 124/481 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs147625837; called by muse, mutect2, varscan2
- SIN3B | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1418982296, COSV99931767; called by muse, varscan2
- SLC12A3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52632921; called by muse, mutect2, varscan2
- SLC18A1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375509247; called by muse, mutect2, varscan2
- SLC1A6 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 127/351 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55669361; called by muse, varscan2
- SLC22A10 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV60422580; called by muse, varscan2
- SLC28A2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs370809865; called by muse, mutect2, varscan2
- SLC39A11 | c.560G>A p.G187D (on ENST00000542342 / NM_001159770.2; = p.G180D on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 243/719 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV55290849; called by muse, varscan2
- SLC6A1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747554856; called by muse, mutect2, varscan2
- SLC9A2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 173/667 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1257344491; called by muse, mutect2, varscan2
- SLCO5A1 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 51/355 reads (14%) | catalogued as rs200135889; called by muse, mutect2, varscan2
- SNAP25 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 113/436 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as rs866969321, COSV54770798, COSV54771307; called by muse, mutect2, varscan2
- SNAP91 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99056321; called by muse, varscan2
- SPATA2 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 199/689 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.595); catalogued as rs768360443; called by muse, varscan2
- SPEN | c.7232C>T p.S2411L | Missense Mutation (SNP) | VAF 148/620 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV65359735; called by muse, varscan2
- SPIC | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 95/421 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV54690911; called by muse, mutect2, varscan2
- SPIDR | c.2506T>C p.F836L | Missense Mutation (SNP) | VAF 135/410 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1456545446; called by muse, mutect2, varscan2
- TAF4B | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1464918681, COSV99299951; called by muse, varscan2
- TANC1 | c.2902G>T p.G968C | Missense Mutation (SNP) | VAF 151/572 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55086025; called by muse, mutect2, varscan2
- TDRD5 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54239472; called by muse, mutect2, varscan2
- TET3 | c.2891G>A p.R964Q | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558784441; called by muse, mutect2, varscan2
- THSD4 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 151/464 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55977991; called by muse, mutect2, varscan2
- TIGD2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs766258790; called by muse, mutect2, varscan2
- TLDC2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 140/475 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs571259365; called by muse, mutect2, varscan2
- TMCO4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 105/505 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs766175122; called by muse, mutect2, varscan2
- TMEM178B | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 138/497 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as rs1382629290; called by muse, mutect2, varscan2
- TMEM178B | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 139/501 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73805201; called by muse, mutect2, varscan2
- TNR | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54902798; called by muse, varscan2
- TNRC6A | c.4837C>T p.R1613C | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1050271217, COSV59370018; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 153/355 reads (43%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRAV10 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 134/464 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270200265; called by muse, varscan2
- TTC6 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1566954798; called by muse, mutect2, varscan2
- TTN | c.33217G>A p.E11073K (on ENST00000591111; = p.E10146K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/672 reads (32%) | PolyPhen benign (0.154); catalogued as COSV60169091; called by muse, mutect2, varscan2
- WSCD2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 133/475 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV54581564; called by muse, mutect2, varscan2
- XIRP2 | c.9182C>T p.P3061L (on ENST00000628543; = p.P3236L on NM_152381.6) | Missense Mutation (SNP) | VAF 128/476 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs375611135, COSV99747455; called by muse, varscan2
- ZAR1L | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 112/570 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs977237682, COSV61525501; called by muse, varscan2
- ZFHX4 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 104/614 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs267601996, COSV50578199; called by muse, mutect2, varscan2
- ZKSCAN3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 158/616 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357110; called by muse, varscan2
- ZSCAN4 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV56595348; called by muse, mutect2, varscan2
- ADAMTS17 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 73/435 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADCY7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 176/644 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- AGO4 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- AHNAK | c.6883_6884dup p.K2296* | Frame Shift Ins (INS) | VAF 70/383 reads (18%) | called by pindel, varscan2
- AK9 | c.3503G>A p.W1168* | Nonsense Mutation (SNP) | VAF 72/287 reads (25%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1131G>C p.E377D | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ANGEL1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 162/571 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.298); called by muse, varscan2
- ANHX | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 109/438 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, varscan2
- ANKIB1 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 77/389 reads (20%) | called by muse, varscan2
- AP3D1 | c.1978_1980delinsCA p.A660Qfs*54 | Frame Shift Del (DEL) | VAF 155/577 reads (27%) | called by pindel, varscan2*
- ARAP1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.07); called by muse, varscan2
- ARFGAP3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 100/396 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, varscan2
- B4GALNT2 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BTBD7 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 205/738 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- C12orf4 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 132/533 reads (25%) | called by muse, mutect2, varscan2
- C14orf39 | c.1398A>T p.E466D | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C16orf78 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, varscan2
- C2CD6 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CASZ1 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 141/550 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); called by muse, varscan2
- CDH16 | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 146/451 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CEP76 | c.1975T>A p.L659I | Missense Mutation (SNP) | VAF 106/216 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CFAP54 | c.8705C>T p.S2902F | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CLEC10A | c.520+6G>A | Splice Region (SNP) | VAF 130/251 reads (52%) | called by muse, mutect2, varscan2
- CNTN5 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 64/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.3453A>G p.V1151= | Splice Region (SNP) | VAF 122/228 reads (54%) | called by muse, mutect2, varscan2
- COL4A5 | c.4195C>T p.P1399S | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CORO7 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 256/753 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CREG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 101/415 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CRIM1 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNND2 | c.2544A>C p.K848N | Missense Mutation (SNP) | VAF 97/620 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DDC | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 95/430 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DGKH | c.3536G>A p.G1179E | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DIS3L2 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 132/571 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- DNAH3 | c.5632G>A p.E1878K | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, varscan2
- DNAH8 | c.11185C>T p.P3729S | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, varscan2
- DOCK3 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 118/331 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DRC1 | c.1791A>T p.E597D | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRICH1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 99/374 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DYNC2I1 | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ENOSF1 | c.1094G>A p.R365K (on ENST00000340116 / NM_001354066.2; = p.R331K on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 94/713 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVPL | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- FAT3 | c.5929G>A p.D1977N | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, varscan2
- FAT3 | c.7213G>A p.E2405K | Missense Mutation (SNP) | VAF 61/325 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- FFAR3 | c.364T>C p.W122R | Missense Mutation (SNP) | VAF 101/554 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.042); called by muse, varscan2
- FLNB | c.6983G>A p.G2328E | Missense Mutation (SNP) | VAF 81/454 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- FLT1 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FUT2 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 130/529 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- GGT7 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 98/396 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, varscan2
- GGT7 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 100/406 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); called by muse, varscan2
- GRIA1 | c.967T>C p.C323R | Missense Mutation (SNP) | VAF 139/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GTPBP3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 234/637 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HECW2 | c.604T>C p.F202L | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- HNRNPH1 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, varscan2
- IGHE | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 180/730 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- IGHG1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 142/632 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, varscan2
- IL17RC | c.1180C>T p.P394S (on ENST00000295981 / NM_153461.4; = p.P308S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/606 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- IL17RC | c.1181C>T p.P394L (on ENST00000295981 / NM_153461.4; = p.P308L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/768 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2
- INPP5B | c.1799C>T p.P600L (on ENST00000373023; = p.P520L on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSRR | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 160/596 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ITGA7 | c.3425C>T p.T1142I (on ENST00000555728; = p.T1098I on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 207/809 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- KCND3 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 173/594 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KDM4F | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KDM4F | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KDM5A | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KLHL29 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 76/408 reads (19%) | called by muse, mutect2, varscan2
- KNTC1 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 59/232 reads (25%) | called by muse, mutect2, varscan2
- LAMC2 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- LLGL1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 194/454 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LMTK3 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- LRRTM4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 83/410 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.044); called by muse, varscan2
- LY75 | c.720G>T p.W240C | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 209/404 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.968); called by muse, varscan2
- MDN1 | c.7253C>T p.S2418F | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MED12 | c.3314A>G p.N1105S | Missense Mutation (SNP) | VAF 188/336 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MIB2 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 126/445 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP19 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 128/490 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MMP19 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 128/491 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MTX1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 284/1063 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC4 | c.12852dup p.T4285Hfs*29 (on ENST00000463781 / NM_018406.7; = p.T49Hfs*29 on NM_004532.6) | Frame Shift Ins (INS) | VAF 164/955 reads (17%) | called by mutect2, pindel, varscan2
- MUC4 | c.4996C>T p.P1666S | Missense Mutation (SNP) | VAF 193/1130 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.65); called by muse, varscan2
- MYO9A | c.7403C>T p.A2468V | Missense Mutation (SNP) | VAF 103/379 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, varscan2
- NAV2 | c.6473C>T p.P2158L (on ENST00000396087 / NM_001244963.2; = p.P2099L on NM_145117.5) | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEA | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 282/975 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NLRP6 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- NOTCH4 | c.2622G>A p.W874* | Nonsense Mutation (SNP) | VAF 262/917 reads (29%) | called by muse, mutect2, varscan2
- NPIPA5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR1B1 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 79/551 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR6C65 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 108/458 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR8B2 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PADI4 | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 138/462 reads (30%) | called by mutect2, varscan2
- PCDHB8 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 142/724 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- PCDHGA4 | c.1462T>A p.Y488N | Missense Mutation (SNP) | VAF 167/413 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- PIGH | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- POU2F3 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPP3CA | c.1048T>A p.F350I | Missense Mutation (SNP) | VAF 156/356 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3A | c.1325T>C p.L442P (on ENST00000554943 / NM_001366432.1; = p.L429P on NM_001284280.1) | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, varscan2
- PTHLH | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTHLH | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RASIP1 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 145/612 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, varscan2
- RHBDL3 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 147/475 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS1 | c.3875C>G p.T1292R | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIPOR2 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 161/523 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- RNASE12 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 146/566 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.172); called by muse, varscan2
- RNF186 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 199/677 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF213 | c.1159_1165del p.I387Ffs*56 | Frame Shift Del (DEL) | VAF 91/414 reads (22%) | called by mutect2, pindel, varscan2
- RPF1 | c.700-15_715del p.X234_splice | Splice Site (DEL) | VAF 64/338 reads (19%) | called by mutect2, pindel, varscan2
- RUNX3 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 218/797 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RXRA | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 194/698 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, varscan2
- SCAF1 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 136/555 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SCN9A | c.2226G>A p.M742I (on ENST00000303354; = p.M731I on NM_002977.3) | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SECISBP2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SERPINB11 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 200/674 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETX | c.7032A>G p.I2344M | Missense Mutation (SNP) | VAF 111/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- SLAIN1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 134/584 reads (23%) | SIFT tolerated (0.64); called by muse, mutect2, varscan2
- SLC2A13 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SLC7A10 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 131/511 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SLFN14 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 160/470 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX15 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SPIRE1 | c.1735C>T p.Q579* (on ENST00000409402 / NM_001128626.2; = p.Q565* on NM_020148.3) | Nonsense Mutation (SNP) | VAF 114/322 reads (35%) | called by muse, mutect2, varscan2
- SSTR4 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 125/497 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- STAB1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 77/475 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STOML3 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 65/328 reads (20%) | called by muse, mutect2, varscan2
- TBC1D16 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 90/648 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMD4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM260 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 106/385 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNC | c.5276G>A p.G1759E | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- TRAF5 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRPC6 | c.600dup p.L201Tfs*5 | Frame Shift Ins (INS) | VAF 72/430 reads (17%) | called by pindel, varscan2
- TSACC | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 169/576 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN10 | c.994T>C p.S332P (on ENST00000574882 / NM_001290212.1; = p.S294P on NM_031945.4) | Missense Mutation (SNP) | VAF 296/898 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPYL5 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 99/781 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.465); called by muse, varscan2
- TXNRD2 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 204/652 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- UBQLN3 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- USP29 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 109/390 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- UXS1 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 188/662 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- VIPAS39 | c.1359C>T p.T453= | Splice Region (SNP) | VAF 66/283 reads (23%) | called by muse, varscan2
- VN1R2 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 144/494 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, varscan2
- XPO7 | c.2068T>C p.F690L | Missense Mutation (SNP) | VAF 94/269 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ZBTB21 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ZBTB21 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZDHHC5 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 76/308 reads (25%) | called by muse, mutect2, varscan2
- ZFX | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 177/327 reads (54%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- ZMYM2 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 58/387 reads (15%) | called by muse, mutect2, varscan2
- ZNF726 | c.964T>A p.F322I | Missense Mutation (SNP) | VAF 152/408 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ABCA13 | c.11889G>A p.V3963= | Silent (SNP) | VAF 77/270 reads (29%) | catalogued as rs1465236321, COSV71294082; called by muse, mutect2, varscan2
- ACE | c.1458C>T p.S486= | Silent (SNP) | VAF 124/408 reads (30%) | catalogued as COSV52004274; called by muse, varscan2
- ACHE | c.216C>T p.P72= | Silent (SNP) | VAF 143/696 reads (21%) | catalogued as rs267601194, COSV99573652; called by muse, mutect2, varscan2
- ACY3 | c.306C>T p.P102= | Silent (SNP) | VAF 92/431 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.252C>T p.A84= | Silent (SNP) | VAF 193/563 reads (34%) | called by muse, mutect2, varscan2
- ADGRD2 | c.1665C>T p.I555= | Silent (SNP) | VAF 110/477 reads (23%) | called by muse, mutect2, varscan2
- AGT | c.429G>A p.L143= | Silent (SNP) | VAF 181/697 reads (26%) | called by muse, varscan2
- AIRE | c.259C>T p.L87= | Silent (SNP) | VAF 150/475 reads (32%) | called by muse, mutect2, varscan2
- ALG2 | c.1047C>T p.P349= | Silent (SNP) | VAF 113/373 reads (30%) | called by muse, mutect2, varscan2
- ANO2 | c.2829G>A p.V943= (on ENST00000356134 / NM_001278597.3; = p.V947= on NM_001278596.3) | Silent (SNP) | VAF 185/659 reads (28%) | called by muse, mutect2, varscan2
- ASAP3 | c.1704C>T p.A568= | Silent (SNP) | VAF 178/646 reads (28%) | called by muse, mutect2, varscan2
- ATAD5 | c.2868T>A p.P956= | Silent (SNP) | VAF 66/236 reads (28%) | called by muse, varscan2
- CA9 | c.1051C>T p.L351= | Silent (SNP) | VAF 76/221 reads (34%) | called by muse, varscan2
- CACNA1H | c.5547C>T p.F1849= | Silent (SNP) | VAF 107/602 reads (18%) | catalogued as rs747094670; called by muse, varscan2
- CCDC180 | c.3651C>T p.L1217= | Silent (SNP) | VAF 90/346 reads (26%) | catalogued as rs768861238; called by muse, mutect2, varscan2
- CCDC87 | c.1455C>T p.N485= | Silent (SNP) | VAF 67/440 reads (15%) | called by muse, mutect2, varscan2
- CEMIP | c.1554C>T p.F518= | Silent (SNP) | VAF 99/373 reads (27%) | catalogued as COSV54991814; called by muse, mutect2, varscan2
- CENPE | c.342C>T p.F114= | Silent (SNP) | VAF 33/204 reads (16%) | catalogued as COSV54390238; called by muse, mutect2, varscan2
- CEP85L | c.16C>T p.L6= | Silent (SNP) | VAF 134/664 reads (20%) | called by muse, varscan2
- CEP85L | c.15C>T p.F5= | Silent (SNP) | VAF 131/662 reads (20%) | called by muse, varscan2
- CNOT1 | c.2703T>C p.F901= | Silent (SNP) | VAF 69/365 reads (19%) | called by muse, varscan2
- CNTN4 | c.2892C>T p.F964= | Silent (SNP) | VAF 174/531 reads (33%) | catalogued as rs748149654, COSV61871927; called by muse, mutect2, varscan2
- CNTNAP5 | c.652C>T p.L218= | Silent (SNP) | VAF 170/550 reads (31%) | catalogued as COSV70507989; called by muse, mutect2, varscan2
- COBLL1 | c.372C>T p.F124= (on ENST00000392717; = p.F86= on NM_014900.5) | Silent (SNP) | VAF 103/416 reads (25%) | called by muse, mutect2, varscan2
- CR2 | c.2532C>T p.I844= | Silent (SNP) | VAF 77/295 reads (26%) | called by muse, mutect2, varscan2
- CRTC2 | c.348C>T p.S116= | Silent (SNP) | VAF 100/375 reads (27%) | called by muse, varscan2
- CSMD1 | c.4317C>T p.F1439= (on ENST00000520002; = p.F1438= on NM_033225.6) | Silent (SNP) | VAF 102/285 reads (36%) | catalogued as COSV59298436; called by muse, mutect2, varscan2
- CTNND2 | c.2064C>T p.I688= | Silent (SNP) | VAF 153/506 reads (30%) | catalogued as COSV58863113; called by muse, mutect2, varscan2
- CUBN | c.7116A>C p.G2372= | Silent (SNP) | VAF 56/295 reads (19%) | called by muse, mutect2, varscan2
- CYB561 | c.453C>T p.S151= | Silent (SNP) | VAF 158/452 reads (35%) | called by muse, varscan2
- CYP2F1 | c.429G>A p.E143= | Silent (SNP) | VAF 133/456 reads (29%) | called by muse, mutect2, varscan2
- CYP4B1 | c.354C>T p.F118= | Silent (SNP) | VAF 113/435 reads (26%) | catalogued as rs867323780; called by muse, mutect2, varscan2
- DCDC1 | c.1302G>A p.K434= | Silent (SNP) | VAF 56/288 reads (19%) | called by muse, mutect2, varscan2
- DCTN2 | c.700C>T p.L234= (on ENST00000548249 / NM_001261413.2; = p.L239= on NM_006400.4) | Silent (SNP) | VAF 116/432 reads (27%) | called by muse, mutect2, varscan2
- DENND1A | c.2739C>T p.P913= | Silent (SNP) | VAF 176/475 reads (37%) | catalogued as rs752736162; called by muse, varscan2
- DENND1A | c.1104T>C p.I368= | Silent (SNP) | VAF 69/270 reads (26%) | called by muse, mutect2, varscan2
- DHRS11 | c.573C>T p.I191= | Silent (SNP) | VAF 137/473 reads (29%) | called by muse, mutect2, varscan2
- DIDO1 | c.1014T>G p.A338= | Silent (SNP) | VAF 108/416 reads (26%) | called by muse, mutect2, varscan2
- DNAH5 | c.7447C>T p.L2483= | Silent (SNP) | VAF 214/774 reads (28%) | called by muse, varscan2
- DNAJA1 | c.1035C>T p.L345= | Silent (SNP) | VAF 96/289 reads (33%) | catalogued as rs1564015672; called by muse, mutect2, varscan2
- DPF3 | c.48C>T p.F16= | Silent (SNP) | VAF 116/388 reads (30%) | called by muse, mutect2, varscan2
- DSCAML1 | c.6309C>T p.A2103= (on ENST00000321322; = p.A2043= on NM_020693.4) | Silent (SNP) | VAF 60/310 reads (19%) | catalogued as rs140170178; called by muse, mutect2, varscan2
- DUOX2 | c.3912G>A p.R1304= | Silent (SNP) | VAF 145/452 reads (32%) | called by muse, mutect2, varscan2
- EFHD1 | c.534C>T p.I178= | Silent (SNP) | VAF 144/622 reads (23%) | catalogued as rs546425742; called by muse, mutect2
- EIF4E1B | c.466C>T p.L156= | Silent (SNP) | VAF 55/299 reads (18%) | called by muse, mutect2, varscan2
- FAM102B | c.462C>T p.S154= | Silent (SNP) | VAF 100/442 reads (23%) | called by muse, mutect2, varscan2
- FAM131C | c.39C>T p.A13= | Silent (SNP) | VAF 109/406 reads (27%) | called by muse, mutect2, varscan2
- FAM209A | c.480G>A p.T160= | Silent (SNP) | VAF 149/479 reads (31%) | catalogued as rs1054364; called by muse, mutect2, varscan2
- FAM214A | c.39A>G p.E13= | Silent (SNP) | VAF 42/256 reads (16%) | called by muse, mutect2, varscan2
- FAM71D | c.720C>T p.I240= | Silent (SNP) | VAF 95/429 reads (22%) | called by muse, mutect2, varscan2
- FAM83A | c.564C>T p.F188= | Silent (SNP) | VAF 68/486 reads (14%) | catalogued as rs1378116226, COSV52683892; called by muse, varscan2
- FAM90A1 | c.453G>A p.P151= | Silent (SNP) | VAF 109/448 reads (24%) | catalogued as rs771226962, COSV56710105; called by muse, mutect2, varscan2
- FHAD1 | c.1077G>A p.K359= | Silent (SNP) | VAF 126/459 reads (27%) | called by muse, mutect2, varscan2
- FRG1 | c.453C>T p.A151= | Silent (SNP) | VAF 79/554 reads (14%) | called by muse, varscan2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 170/574 reads (30%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GALNT14 | c.591C>T p.F197= | Silent (SNP) | VAF 143/445 reads (32%) | called by muse, varscan2
- GPR55 | c.573C>A p.L191= | Silent (SNP) | VAF 159/592 reads (27%) | called by muse, mutect2, varscan2
- GPRC5C | c.222C>T p.P74= (on ENST00000652232; = p.P29= on NM_018653.4) | Silent (SNP) | VAF 173/632 reads (27%) | catalogued as rs147345722; called by muse, mutect2, varscan2
- HCAR2 | c.195C>T p.F65= | Silent (SNP) | VAF 130/535 reads (24%) | catalogued as rs746448105; called by muse, varscan2
- HOXB4 | c.585C>T p.I195= | Silent (SNP) | VAF 106/600 reads (18%) | catalogued as rs1394962550, COSV100203839; called by muse, varscan2
- HOXD11 | c.279C>T p.P93= | Silent (SNP) | VAF 62/186 reads (33%) | called by muse, varscan2
- HTR1E | c.792G>A p.R264= | Silent (SNP) | VAF 135/502 reads (27%) | catalogued as COSV59508864; called by mutect2, varscan2
- HTR3A | c.846G>A p.L282= | Silent (SNP) | VAF 70/434 reads (16%) | called by muse, varscan2
- HTT | c.7356C>A p.R2452= | Silent (SNP) | VAF 76/219 reads (35%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.33C>T p.L11= | Silent (SNP) | VAF 155/618 reads (25%) | called by muse, mutect2, varscan2
- IGLV6-57 | c.102G>A p.G34= | Silent (SNP) | VAF 112/493 reads (23%) | catalogued as rs539326442; called by muse, mutect2, varscan2
- INPP4A | c.2371C>T p.L791= (on ENST00000074304 / NM_001134224.1; = p.L752= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 160/558 reads (29%) | called by muse, varscan2
- INSRR | c.1644G>A p.V548= | Silent (SNP) | VAF 143/536 reads (27%) | called by muse, mutect2, varscan2
- ITIH4 | c.1566G>A p.T522= | Silent (SNP) | VAF 41/362 reads (11%) | called by muse, mutect2, varscan2
- KMT2B | c.6837G>A p.K2279= | Silent (SNP) | VAF 178/627 reads (28%) | catalogued as rs1387911005; called by muse, varscan2
- KRT77 | c.645G>A p.L215= | Silent (SNP) | VAF 140/544 reads (26%) | catalogued as rs1177292474; called by muse, mutect2
- LAMC2 | c.3051C>T p.I1017= | Silent (SNP) | VAF 94/420 reads (22%) | called by muse, mutect2
- LEMD3 | c.1053C>A p.S351= | Silent (SNP) | VAF 135/588 reads (23%) | catalogued as COSV100384106; called by mutect2, varscan2
- LRRC30 | c.33G>A p.K11= | Silent (SNP) | VAF 134/342 reads (39%) | catalogued as rs1424813774, COSV101274428; called by muse, mutect2, varscan2
- MACC1 | c.618G>A p.Q206= | Silent (SNP) | VAF 146/480 reads (30%) | called by muse, varscan2
- MAP3K20 | c.777C>T p.I259= | Silent (SNP) | VAF 134/491 reads (27%) | called by muse, mutect2, varscan2
- MCM7 | c.2148C>T p.I716= | Silent (SNP) | VAF 92/434 reads (21%) | called by muse, varscan2
- MED13L | c.2739C>T p.F913= | Silent (SNP) | VAF 122/502 reads (24%) | catalogued as COSV56124846; called by muse, mutect2, varscan2
- MMP19 | c.1008C>T p.N336= | Silent (SNP) | VAF 114/509 reads (22%) | called by muse, mutect2, varscan2
- MMP26 | c.609C>T p.F203= | Silent (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- MROH2B | c.1317G>A p.L439= | Silent (SNP) | VAF 116/452 reads (26%) | called by muse, mutect2, varscan2
- MROH2B | c.378T>G p.P126= | Silent (SNP) | VAF 105/395 reads (27%) | called by muse, mutect2, varscan2
- MTOR | c.6012C>T p.T2004= | Silent (SNP) | VAF 111/378 reads (29%) | called by muse, mutect2, varscan2
- MUC16 | c.27018G>A p.E9006= | Silent (SNP) | VAF 168/438 reads (38%) | called by muse, varscan2
- MYH8 | c.5083C>T p.L1695= | Silent (SNP) | VAF 207/532 reads (39%) | called by muse, mutect2, varscan2
- NALCN | c.1236G>A p.R412= | Silent (SNP) | VAF 76/296 reads (26%) | catalogued as COSV51923434; called by muse, mutect2, varscan2
- NAV2 | c.6474C>T p.P2158= (on ENST00000396087 / NM_001244963.2; = p.P2099= on NM_145117.5) | Silent (SNP) | VAF 79/409 reads (19%) | called by muse, mutect2, varscan2
- NDRG3 | c.471C>T p.G157= (on ENST00000349004 / NM_032013.4; = p.G145= on NM_022477.4) | Silent (SNP) | VAF 112/368 reads (30%) | called by muse, mutect2, varscan2
- NEDD4L | c.2235C>T p.T745= (on ENST00000400345 / NM_001144967.3; = p.T725= on NM_015277.6) | Silent (SNP) | VAF 93/417 reads (22%) | called by muse, mutect2, varscan2
- NEDD4L | c.2236C>T p.L746= (on ENST00000400345 / NM_001144967.3; = p.L726= on NM_015277.6) | Silent (SNP) | VAF 92/409 reads (22%) | catalogued as COSV99895310; called by muse, mutect2, varscan2
- NEXMIF | c.1332C>T p.S444= | Silent (SNP) | VAF 206/354 reads (58%) | called by muse, varscan2
- NISCH | c.4134C>T p.S1378= | Silent (SNP) | VAF 94/568 reads (17%) | catalogued as rs1245861751; called by muse, varscan2
- NLRP7 | c.1173G>A p.T391= | Silent (SNP) | VAF 246/1049 reads (23%) | catalogued as rs780110978; called by muse, mutect2, varscan2
- NPC1 | c.2077C>T p.L693= | Silent (SNP) | VAF 149/517 reads (29%) | called by muse, mutect2, varscan2
- NR4A3 | c.1563C>A p.S521= | Silent (SNP) | VAF 184/625 reads (29%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.343C>T p.L115= | Silent (SNP) | VAF 113/445 reads (25%) | catalogued as rs1391282209; called by muse, varscan2
- OR2L2 | c.75C>T p.F25= | Silent (SNP) | VAF 89/395 reads (23%) | catalogued as rs201120288, COSV63551743; called by muse, mutect2, varscan2
- OR2T8 | c.51C>T p.N17= | Silent (SNP) | VAF 114/459 reads (25%) | called by muse, mutect2
- OR4A15 | c.264G>A p.K88= | Silent (SNP) | VAF 73/354 reads (21%) | catalogued as rs373928337; called by muse, mutect2, varscan2
- OR4M1 | c.429C>T p.I143= | Silent (SNP) | VAF 166/621 reads (27%) | catalogued as rs763163557; called by muse, varscan2
- OR6K2 | c.465C>T p.P155= | Silent (SNP) | VAF 102/404 reads (25%) | catalogued as rs895546338, COSV62744092; called by muse, mutect2, varscan2
- OR6V1 | c.627C>T p.F209= | Silent (SNP) | VAF 319/910 reads (35%) | called by muse, mutect2, varscan2
- OR8J1 | c.936C>T p.S312= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as rs148720229; called by muse, varscan2
- ORC1 | c.927G>A p.K309= | Silent (SNP) | VAF 116/385 reads (30%) | called by muse, mutect2, varscan2
- OVGP1 | c.1668C>T p.T556= | Silent (SNP) | VAF 162/525 reads (31%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1332C>T p.L444= (on ENST00000259318 / NM_001136562.3; = p.L675= on NM_007203.5) | Silent (SNP) | VAF 160/588 reads (27%) | catalogued as rs780836774; called by muse, varscan2
- PARP3 | c.795C>T p.F265= | Silent (SNP) | VAF 72/493 reads (15%) | catalogued as rs760388246, COSV99232235; called by muse, varscan2
- PCF11 | c.2511A>G p.P837= | Silent (SNP) | VAF 78/414 reads (19%) | called by muse, mutect2, varscan2
- PDZD7 | c.1302C>T p.S434= | Silent (SNP) | VAF 204/429 reads (48%) | catalogued as rs1358462226; called by muse, varscan2
- PI16 | c.762C>T p.T254= | Silent (SNP) | VAF 182/674 reads (27%) | called by muse, mutect2, varscan2
- PIAS3 | c.1386C>T p.P462= | Silent (SNP) | VAF 175/661 reads (26%) | called by muse, mutect2, varscan2
- PIGQ | c.1497G>A p.L499= | Silent (SNP) | VAF 130/422 reads (31%) | called by muse, varscan2
- PIK3CD | c.286C>T p.L96= | Silent (SNP) | VAF 213/790 reads (27%) | catalogued as rs774791238; called by muse, mutect2, varscan2
- PLCZ1 | c.1726C>T p.L576= | Silent (SNP) | VAF 72/251 reads (29%) | catalogued as COSV56850406; called by muse, mutect2, varscan2
- PLSCR3 | c.825C>T p.F275= | Silent (SNP) | VAF 134/298 reads (45%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1479A>G p.Q493= | Silent (SNP) | VAF 186/500 reads (37%) | called by muse, mutect2, varscan2
- POLG2 | c.678T>C p.N226= | Silent (SNP) | VAF 87/279 reads (31%) | called by muse, mutect2, varscan2
- PRUNE2 | c.7860G>A p.T2620= | Silent (SNP) | VAF 123/438 reads (28%) | catalogued as COSV65043504; called by muse, mutect2, varscan2
- PSD | c.705C>T p.I235= | Silent (SNP) | VAF 207/464 reads (45%) | catalogued as rs757010456, COSV50050441, COSV50068454; called by muse, mutect2, varscan2
- PYHIN1 | c.630C>T p.F210= | Silent (SNP) | VAF 66/324 reads (20%) | catalogued as COSV63723729; called by muse, varscan2
- PZP | c.3888C>T p.F1296= | Silent (SNP) | VAF 120/424 reads (28%) | called by muse, varscan2
- PZP | c.339C>T p.F113= | Silent (SNP) | VAF 158/564 reads (28%) | catalogued as COSV54363494; called by muse, mutect2, varscan2
- QTRT2 | c.429C>T p.C143= | Silent (SNP) | VAF 84/232 reads (36%) | called by muse, varscan2
- RASGRP2 | c.1389C>T p.A463= | Silent (SNP) | VAF 66/320 reads (21%) | called by muse, mutect2, varscan2
- RBP7 | c.189G>A p.V63= | Silent (SNP) | VAF 154/478 reads (32%) | catalogued as COSV53813653; called by muse, mutect2, varscan2
- RFWD3 | c.2019A>C p.R673= | Silent (SNP) | VAF 129/308 reads (42%) | called by muse, varscan2
- RIMS1 | c.384C>T p.C128= | Silent (SNP) | VAF 158/471 reads (34%) | catalogued as rs914659964, COSV53462888; called by muse, mutect2, varscan2
- RNF114 | c.225C>T p.V75= | Silent (SNP) | VAF 180/617 reads (29%) | called by muse, varscan2
- SALL3 | c.2967G>A p.K989= | Silent (SNP) | VAF 250/854 reads (29%) | catalogued as rs1295855931, COSV73306165; called by muse, varscan2
- SCART1 | c.2235C>T p.F745= | Silent (SNP) | VAF 204/413 reads (49%) | called by muse, mutect2, varscan2
- SLC25A26 | c.673C>T p.L225= | Silent (SNP) | VAF 172/488 reads (35%) | called by muse, mutect2, varscan2
- SLC26A11 | c.1137G>A p.A379= | Silent (SNP) | VAF 101/613 reads (16%) | catalogued as COSV63281490; called by muse, varscan2
- SLC7A10 | c.483C>T p.S161= | Silent (SNP) | VAF 131/506 reads (26%) | catalogued as COSV53505628; called by muse, mutect2, varscan2
- SLCO1B1 | c.945A>T p.G315= | Silent (SNP) | VAF 73/257 reads (28%) | called by muse, varscan2
- SLCO6A1 | c.795C>T p.I265= | Silent (SNP) | VAF 67/192 reads (35%) | called by muse, mutect2, varscan2
- SORBS1 | c.3387G>A p.R1129= | Silent (SNP) | VAF 224/464 reads (48%) | catalogued as COSV99528105; called by muse, mutect2, varscan2
- SOX12 | c.105C>T p.T35= | Silent (SNP) | VAF 235/816 reads (29%) | called by muse, varscan2
- SRRM2 | c.3234G>A p.Q1078= | Silent (SNP) | VAF 64/356 reads (18%) | called by muse, mutect2, varscan2
- SSC5D | c.4060C>T p.L1354= | Silent (SNP) | VAF 194/829 reads (23%) | called by muse, varscan2
- SUN1 | c.330G>A p.Q110= (on ENST00000405266 / NM_001367651.1; = p.Q60= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 154/485 reads (32%) | called by muse, varscan2
- SZT2 | c.1164G>A p.K388= | Silent (SNP) | VAF 130/510 reads (25%) | called by muse, varscan2
- TBCD | c.2271C>T p.I757= | Silent (SNP) | VAF 130/403 reads (32%) | called by muse, varscan2
- TEKT5 | c.984G>A p.S328= | Silent (SNP) | VAF 61/400 reads (15%) | catalogued as rs1171439092, COSV51590763; called by muse, varscan2
- TENM1 | c.654G>A p.R218= | Silent (SNP) | VAF 213/325 reads (66%) | catalogued as rs751565049, COSV64445586; called by muse, mutect2, varscan2
- TERF2IP | c.951C>T p.I317= | Silent (SNP) | VAF 148/395 reads (37%) | called by muse, varscan2
- TET3 | c.2892G>A p.R964= | Silent (SNP) | VAF 88/362 reads (24%) | called by muse, mutect2, varscan2
- TET3 | c.4314C>T p.Y1438= | Silent (SNP) | VAF 146/470 reads (31%) | catalogued as rs778156069; called by muse, varscan2
- TFEC | c.423G>A p.K141= | Silent (SNP) | VAF 51/283 reads (18%) | catalogued as COSV55400033; called by muse, mutect2, varscan2
- THNSL2 | c.738G>A p.L246= | Silent (SNP) | VAF 117/582 reads (20%) | called by muse, mutect2, varscan2
- TIGD2 | c.879C>T p.F293= | Silent (SNP) | VAF 56/305 reads (18%) | catalogued as COSV57647802; called by muse, varscan2
- TMEM132B | c.2472G>A p.Q824= | Silent (SNP) | VAF 161/540 reads (30%) | catalogued as COSV100170352; called by muse, mutect2, varscan2
- TMEM98 | c.147C>T p.L49= | Silent (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.876C>T p.F292= | Silent (SNP) | VAF 74/500 reads (15%) | catalogued as rs752933989; called by muse, mutect2, varscan2
- TP53I3 | c.372C>T p.A124= | Silent (SNP) | VAF 131/467 reads (28%) | catalogued as rs1262332567; called by muse, mutect2, varscan2
- TRAIP | c.1143G>A p.L381= | Silent (SNP) | VAF 68/502 reads (14%) | called by muse, mutect2, varscan2
- TRIOBP | c.3063G>A p.R1021= | Silent (SNP) | VAF 328/1032 reads (32%) | called by muse, varscan2
- TRPV5 | c.1869C>T p.F623= | Silent (SNP) | VAF 293/780 reads (38%) | catalogued as rs758731434, COSV54682761; called by muse, mutect2, varscan2
- TSEN2 | c.1209C>T p.S403= | Silent (SNP) | VAF 123/435 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.28251G>A p.G9417= (on ENST00000591111; = p.G8490= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/458 reads (22%) | catalogued as COSV100611625; called by muse, varscan2
- VIT | c.1809G>A p.G603= (on ENST00000389975 / NM_001177969.1; = p.G618= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/412 reads (19%) | called by muse, varscan2
- VPS39 | c.2215C>T p.L739= (on ENST00000348544 / NM_001301138.2; = p.L728= on NM_015289.5) | Silent (SNP) | VAF 78/278 reads (28%) | called by muse, mutect2, varscan2
- VWA8 | c.4422C>T p.L1474= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as COSV65002160; called by muse, varscan2
- WDR19 | c.60C>T p.A20= | Silent (SNP) | VAF 121/290 reads (42%) | catalogued as rs777240456; called by muse, mutect2, varscan2
- WDR49 | c.234C>T p.F78= (on ENST00000308378 / NM_001366158.1; = p.F419= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 81/212 reads (38%) | catalogued as rs367736932; called by muse, mutect2, varscan2
- XDH | c.108G>A p.L36= | Silent (SNP) | VAF 74/382 reads (19%) | called by muse, mutect2, varscan2
- XIRP2 | c.8274C>T p.S2758= (on ENST00000628543; = p.S2933= on NM_152381.6) | Silent (SNP) | VAF 95/382 reads (25%) | catalogued as rs778262913; called by muse, mutect2, varscan2
- ZCCHC14 | c.111C>T p.G37= (on ENST00000268616; = p.G174= on NM_015144.3) | Silent (SNP) | VAF 224/538 reads (42%) | catalogued as rs761735577; called by muse, mutect2, varscan2
- ZCCHC2 | c.633G>A p.E211= | Silent (SNP) | VAF 242/914 reads (26%) | catalogued as rs1188413896; called by muse, varscan2
- ZIC1 | c.696C>T p.P232= | Silent (SNP) | VAF 219/512 reads (43%) | catalogued as COSV51556274, COSV99291929; called by muse, varscan2
- ZNF211 | c.432C>T p.F144= (on ENST00000347302 / NM_198855.4; = p.F157= on NM_006385.5) | Silent (SNP) | VAF 144/611 reads (24%) | catalogued as rs1373268445; called by muse, mutect2, varscan2
- ZNF488 | c.549G>A p.G183= | Silent (SNP) | VAF 231/541 reads (43%) | catalogued as rs781805678; called by muse, mutect2, varscan2
- ZNF532 | c.1530C>T p.S510= | Silent (SNP) | VAF 166/644 reads (26%) | catalogued as rs1476977616; called by muse, varscan2
- ZNF813 | c.348C>T p.I116= | Silent (SNP) | VAF 137/510 reads (27%) | catalogued as COSV67177321; called by muse, mutect2, varscan2
- ZNF98 | c.1341A>C p.S447= | Silent (SNP) | VAF 132/249 reads (53%) | called by muse, varscan2
- ADNP | chr20:50889934 G>A | 3'Flank (SNP) | VAF 135/404 reads (33%) | catalogued as rs997849120; called by muse, mutect2, varscan2
- GABRD | c.554-19C>T | Intron (SNP) | VAF 203/684 reads (30%) | catalogued as rs1350010262; called by muse, varscan2
- GOLGA6L2 | c.*2A>T | 3'UTR (SNP) | VAF 104/357 reads (29%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+122C>T | Intron (SNP) | VAF 205/615 reads (33%) | called by muse, mutect2, varscan2
- KCNK4 | c.*35C>T | 3'UTR (SNP) | VAF 116/616 reads (19%) | catalogued as rs913774489; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7644C>T | Intron (SNP) | VAF 55/288 reads (19%) | called by muse, mutect2, varscan2
- MAGI1 | c.3635-1972G>A | Intron (SNP) | VAF 136/478 reads (28%) | catalogued as rs778591970, COSV100440603; called by muse, mutect2, varscan2
- MAP4 | c.2000-14277C>A | Intron (SNP) | VAF 48/312 reads (15%) | called by muse, varscan2
- MED24 | c.-6G>A | 5'UTR (SNP) | VAF 193/664 reads (29%) | called by muse, mutect2, varscan2
- MPP2 | c.32-2094G>A | Intron (SNP) | VAF 51/312 reads (16%) | called by muse, varscan2
- OGFOD3 | c.824-1866C>T | Intron (SNP) | VAF 86/305 reads (28%) | called by muse, varscan2
- SEMA4D | chr9:89376981 C>T | 3'Flank (SNP) | VAF 177/656 reads (27%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+92C>T | Intron (SNP) | VAF 54/378 reads (14%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3008C>T | Intron (SNP) | VAF 124/325 reads (38%) | called by muse, mutect2
- UNC13B | c.762-3007T>C | Intron (SNP) | VAF 110/283 reads (39%) | called by muse, mutect2, varscan2
- UTS2B | chr3:191262873 T>C | 3'Flank (SNP) | VAF 132/356 reads (37%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.610+204T>C | Intron (SNP) | VAF 67/367 reads (18%) | called by muse, mutect2, varscan2
